Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A23H, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A23H-01A (Primary Tumor).

[page 1 of 3]
1CB-0-3

Carcinoma, infiltrating ductal, NOS 8500/3

Site: Breast, NOS C50.9

hw 4/19/11

MRN: [REDACTED]
Surgerv

OV

Age: Y Sex: F
DOB: [REDACTED]Laboratory Patient Report
Print Date/Time:

Surgical Pathology

Reviewed Initials		

KME [REDACTED] hw 4/19/11

Histopathological Examination

Path#:

Collected:

Received:

Complete: (

Pre-Op Diagnosis : Right Breast Cancer
Order Physician :
Specimens : Breast, right breast, white/lateral, black/superior
Frozen Diagnosis :

Report : GROSS EXAMINATION:

The specimen is received in a container labeled with the name of the patient and identified as breast, right breast. The specimen consists of a simple mastectomy measuring en bloc 15.5 x 9.5 x 3.1 and weighs 115 grams. There is an anterior ellipse of skin measuring 16.5 x 7.5 cm with an eccentric 2.7 cm areolar complex with everted nipple. Sections of nipple areola are sampled in block 1. The skin surface shows a 4 cm long scar located near the lateral margin and is sampled in block 2. The superficial superior margin is inked orange and the superficial inferior margin is inked green. The deep margin is inked black and the specimen sectioned, showing a firm pale tan mass measuring 4.2 x 3.7 x 2.9 cm. The mass is located in the upper inner and lower inner quadrants. The mass grossly extends to the inked deep margin and is 1.7 cm from the superficial superior margin and 1.9 cm from the superficial inferior margin. The skin overlying the mass is disrupted. Sections of the mass are submitted in blocks 3-7. The remaining breast is composed of yellow lobulated adipose tissue admixed with islands of gray-white rubbery tissue. The breast is divided into four quadrants, upper inner, lower inner, upper outer and lower outer and sampled in blocks 8-11 respectively. No axillary tissue is grossly identified. Formalin fixation time is approximately 12 hours.

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

Breast, right simple mastectomy:
- Invasive ductal carcinoma of breast, grade 2, extending to within 0.4 mm of the deep margin (see cancer case summary)

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #:
Visit #:

[page 2 of 3]
check

- Tumor present within dermis and dermal lymphatics.

SPECIMEN: Total breast (including nipple and skin)
PROCEDURE: Simple mastectomy
LYMPH NODE SAMPLING: No lymph nodes present
SPECIMEN INTEGRITY: Single intact specimen (margins can be evaluated)
SPECIMEN LATERALITY: Right
TUMOR SITE (Invasive Carcinoma): Upper and lower inner quadrant
TUMOR SIZE (Invasive Carcinoma):
Greatest dimension: 4.2 x 3.7 x 2.9 cm
TUMOR FOCALITY: Single focus of invasive carcinoma

MACROSCOPIC AND MICROSCOPIC EXTENT OF TUMOR:
Skin: Invasive carcinoma directly invades into the dermis without skin ulceration
Nipple: DCIS does not involve nipple epidermis
Skeletal Muscle: No skeletal muscle present
DUCTAL CARCINOMA IN SITU (DCIS): No DCIS is present
LOBULAR CARCINOMA IN SITU (LCIS): Not identified
HISTOLOGIC TYPE OF INVASIVE CARCINOMA: Invasive ductal carcinoma (no special type or not otherwise specified)
HISTOLOGIC GRADE: NOTTINGHAM HISTOLOGIC SCORE:
Glandular (Acinar)/Tubular Differentiation: 3
Nuclear Pleomorphism: 2
Mitotic Count: 2
Overall Grade: Grade 2, score 7 (scores of 6 or 7)

MARGINS: Uninvolved by invasive carcinoma
Distance of closest margin: 0.4 mm
Specify margin: Deep margin

PATHOLOGIC STAGING (pTNM):
Primary Tumor (Invasive Carcinoma)(pT):
pT2: Tumor greater than 20 mm but < or = 50 mm
Regional Lymph Nodes (pN): pNX: Cannot be assessed
Distant Metastasis (M): Not applicable

ANCILLARY STUDIES:

Estrogen Receptor:

Performed on another specimen (TML accession #

Results: Immunoreactive tumor cells present.

Quantitation: 1-2+, 10% of cells staining.

Progesterone Receptor:

Performed on another specimen (TML accession #

Results: No immunoreactive tumor cells present.

HER2/neu:

Immunoperoxidase Studies: Performed on another specimen (TML #

Results: Positive, score 3+

Fluorescence In Situ Hybridization (FISH) for HER2/neu:

Performed on another specimen

Results: Amplified, ratio 5.90

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #:
Visit #:

Page 2 of 3

[page 3 of 3]
MICROSCOPIC FINDINGS: Present in neoplastic tissue
CLINICAL HISTORY: Palpable mass.

SUMMARY OF PATHOLOGIC STAGING: pT2NXG2

Intradepartmental consultation obtained.

, M.D., Pathologist

Electronically Signed by:
, MD

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #:
Visit #:

Page 3 of 3

Source: NCI Genomic Data Commons file 7b371cfd-eae5-4236-aed0-e87672331799 (TCGA-AC-A23H.A7C7D409-D086-4A9B-8C8F-E7E231D5891D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).